Somatic mutation profile of tumor specimen TCGA-EO-A22Y-01A (aliquot TCGA-EO-A22Y-01A-11D-A17W-09) from TCGA case TCGA-EO-A22Y, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 68.8 years (25,127 days).
Specimen TCGA-EO-A22Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e476afe6-4781-4f07-b921-b0e6a0fd94cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A22Y-10A (Blood Derived Normal), aliquot TCGA-EO-A22Y-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d00c5543-9fc4-425c-8e8c-000b1971ed47

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 36, Silent 13, Nonsense Mutation 3, In Frame Del 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD4 | c.3341G>A p.R1114Q (on ENST00000357008 / NM_001363606.2; = p.R1127Q on NM_001273.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs886039917, COSV58895679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786204856, CD132274, CM110120, COSV64288477, COSV64302636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGO3 | c.1899G>T p.Q633H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99869555; called by muse, mutect2, varscan2
- AMER2 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63436764, COSV63439765; called by muse, mutect2, varscan2
- ARHGAP35 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 23/34 reads (68%) | catalogued as COSV68329300; called by muse, mutect2, varscan2
- ARID1A | c.6703G>C p.A2235P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100253775; called by muse, mutect2, varscan2
- ARL13A | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs766355429, COSV65880327; called by muse, mutect2, varscan2
- ATP8B1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757077093, COSV99376766; called by muse, mutect2, varscan2
- BNC1 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs757220105, COSV100596948; called by muse, mutect2, varscan2
- CCDC22 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs782649538, COSV100873280; called by muse, mutect2, varscan2
- CDC14A | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs371468460, COSV100325925; called by muse, mutect2, varscan2
- CHD4 | c.2513C>T p.S838F (on ENST00000357008 / NM_001363606.2; = p.S851F on NM_001273.5) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58898168; called by muse, mutect2, varscan2
- CHODL | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100167135; called by muse, mutect2
- COX4I2 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs759441417, COSV101064286; called by muse, mutect2, varscan2
- DIPK2B | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as rs755578524, COSV65005805; called by muse, mutect2, varscan2
- DISP3 | c.1813G>A p.V605M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs868180437, COSV53830506, COSV99610200; called by muse, mutect2, varscan2
- ECRG4 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1298098125, COSV52999902; called by muse, mutect2, varscan2
- FEM1C | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99174455; called by muse, mutect2, varscan2
- FUS | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs776191869, COSV99569093; called by muse, mutect2, varscan2
- GIGYF2 | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100771626; called by muse, mutect2, varscan2
- GK2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.631); catalogued as COSV62626108; called by muse, mutect2, varscan2
- GLI3 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV101230133, COSV67887651; called by muse, mutect2, varscan2
- HAUS6 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV100997760, COSV100997923; called by muse, mutect2, varscan2
- LIN7B | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs150018101; called by muse, mutect2, varscan2
- MB21D2 | c.1371del p.K457Nfs*5 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs34835215; called by mutect2, pindel, varscan2
- MUC16 | c.36724C>A p.Q12242K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV101202075; called by muse, mutect2
- NPPA | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1803268, COSV56742385; called by muse, mutect2, varscan2
- NRAP | c.1732G>A p.A578T (on ENST00000359988 / NM_001322945.2; = p.A543T on NM_006175.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV100748658, COSV63491156; called by muse, mutect2, varscan2
- OR6C75 | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs751099609, COSV100595477; called by muse, mutect2, varscan2
- POTEE | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.964); catalogued as rs747401333, COSV100389229; called by muse, mutect2, varscan2
- RMND1 | c.293T>A p.M98K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100323824; called by muse, mutect2, varscan2
- STT3A | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs763378756, COSV101205315, COSV67064777; called by muse, mutect2, varscan2
- TBX5 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1486871388, COSV59861015, COSV59862601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPR | c.3452A>C p.D1151A | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV100824287; called by muse, mutect2, varscan2
- USP13 | c.4C>A p.Q2K | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99831866; called by muse, mutect2, varscan2
- WTAP | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61610446, COSV61610540; called by muse, mutect2, varscan2
- XYLT1 | c.2384A>G p.Y795C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99763092, COSV99763622; called by muse, mutect2, varscan2
- ZBP1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs754610408, COSV100474089; called by muse, mutect2, varscan2
- ZHX2 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58711128; called by muse, mutect2, varscan2
- ZNF536 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs763225279, COSV62826124; called by muse, mutect2, varscan2
- NFRKB | c.3548_3556del p.R1183_V1186delinsL (on ENST00000446488 / NM_001143835.2; = p.R1208_V1211delinsL on NM_006165.3) | In Frame Del (DEL) | VAF 36/51 reads (71%) | called by mutect2, pindel, varscan2
- SUPT6H | c.1667_1669del p.R556del | In Frame Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- BACH1 | c.462C>T p.D154= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs762789684, COSV99728797; called by muse, mutect2, varscan2
- BPIFC | c.315G>A p.A105= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs148657721; called by muse, mutect2, varscan2
- CHEK2 | c.621T>C p.S207= (on ENST00000382580 / NM_001005735.2; = p.S164= on NM_007194.4) | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100102684; called by muse, mutect2, varscan2
- COMMD8 | c.471T>C p.S157= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV101055810; called by muse, mutect2, varscan2
- DGKK | c.555G>A p.P185= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs1557234356, COSV101053258; called by muse, mutect2, varscan2
- DIAPH2 | c.39C>T p.G13= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs914979197, COSV61266327; called by muse, mutect2, varscan2
- DSCAM | c.867C>A p.G289= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV101261722; called by muse, mutect2, varscan2
- FAM47A | c.864C>T p.D288= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as rs375410896, COSV60494111; called by muse, mutect2, varscan2
- GPRC5A | c.741C>T p.S247= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs200045600, COSV99185610; called by muse, mutect2, varscan2
- KDM8 | c.894C>T p.G298= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs761229989, COSV53728174; called by muse, mutect2, varscan2
- RABGGTA | c.205C>A p.R69= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99397784, COSV99397866; called by muse, mutect2
- TST | c.102G>A p.A34= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99968273; called by muse, mutect2, varscan2
- ZNF70 | c.1077C>T p.T359= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs748528517, COSV100558972; called by muse, mutect2, varscan2
